Gene-level copy-number profile of tumor specimen TCGA-B0-4707-01A from TCGA case TCGA-B0-4707, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 63.9 years (23,322 days).
Specimen TCGA-B0-4707-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.5122aa39-380c-49d2-9c8e-62cd337962e5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B0-4707-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dd45042e-5012-4ec7-b897-e5cae3d0032b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,376; copy number 2: 23,092; copy number 3: 13,996; copy number 4: 12,378; copy number 5: 8,715; copy number 6: 190; copy number 7: 61; copy number 9: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-B0-4707-01): tumor purity 0.4, ploidy 3.05, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:4,299,390–4,306,046, 1 gene: AL162419.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,975 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–190,203,484, 3,198 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr2:190,607,660–198,772,356, 96 genes, copy number 6 (broad region; genes not listed).
- chr5:58,198–181,342,213, 2,985 genes, copy number 5 (broad region; genes not listed).
- chr7:70,972–2,394,131, 67 genes, copy number 6 (broad region; genes not listed).
- chr8:100,776,512–102,412,759, 41 genes, copy number 5 (within-gene range 4–5): RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3, GRHL2, AP001207.2, AP001207.1, NCALD, AP000426.1, AP001329.1, PDCL3P2, MIR5680, AP001328.1, RRM2B, UBR5-AS1, SUMO2P19, UBR5, AP002907.1.
- chr8:144,789,765–145,066,685, 15 genes, copy number 6: RPL8, MIR6850, ZNF517, ZNF7, COMMD5, AF235103.3, ZNF250, ZNF16, ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr11:6,395,124–7,882,947, 52 genes, copy number 5 (within-gene range 2–5): APBB1, HPX, TRIM3, ARFIP2, AC084337.2, TIMM10B, AC084337.1, DNHD1, RRP8, AC091564.2, ILK, TAF10, AC091564.3, AC091564.7, TPP1, AC091564.6, DCHS1, AC091564.4, AC091564.5, MRPL17, AC091564.1, GVINP1, GVINP2, OR2AG2, OR2AG1, OR6A2, AC087280.2, AC087280.1, OR10A5, OR10A2, OR10A4, OR2D2, OR2D3, ZNF215, ZNF214, NLRP14, RBMXL2, AC027804.1, MIR302E, SYT9, AC107884.1, OLFML1, PPFIBP2, AC107884.2, CYB5R2, OVCH2, AC104237.2, AC104237.3, AC044810.3, AC104237.1, OR10AB1P, OR5P4P.
- chr11:7,772,890–7,796,973, 3 genes, copy number 5: OR5P1P, AC044810.1, OR5P2.
- chr11:41,518,895–41,714,492, 1 gene, copy number 5 (within-gene range 2–5): LINC02741.
- chr11:41,660,030–48,170,841, 157 genes, copy number 5–9 (within-gene range 2–9) (broad region; genes not listed).
- chr11:80,527,960–82,718,299, 12 genes, copy number 6 (within-gene range 2–6): RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25, MIR4300HG, AP002802.2, MIR4300, AP002802.1.
- chr11:100,336,856–100,993,941, 6 genes, copy number 5 (within-gene range 2–5): RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115.
- chr11:116,496,899–122,981,834, 194 genes, copy number 5 (broad region; genes not listed).
- chr12:132,457,160–133,214,832, 41 genes, copy number 5: AC079031.1, AC079031.2, FBRSL1, AC131212.3, AC131212.2, MIR6763, AC131212.1, LRCOL1, P2RX2, AC131212.4, POLE, PXMP2, AC135586.2, PGAM5, RNA5SP379, ANKLE2, AC135586.1, GOLGA3, CHFR, RPS11P5, RNU6-327P, AC127070.4, AC127070.1, AC127070.3, AC127070.2, ZNF605, NANOGNBP2, ZNF26, RNU4ATAC12P, ZNF84-DT, PTP4A1P2, ZNF84, AC073911.1, AC073911.2, ZNF140, ZNF891, AC026786.2, RPL23AP67, ZNF10, AC026786.1, ZNF268.
- chr19:6,887,566–9,268,819, 120 genes, copy number 5 (broad region; genes not listed).
- chr19:16,355,239–16,472,085, 1 gene, copy number 5 (within-gene range 2–5): EPS15L1.
- chr19:16,412,684–17,419,324, 59 genes, copy number 5: AC020917.1, AC020917.2, CALR3, AC008764.1, C19orf44, CHERP, RN7SL146P, AC008764.6, SLC35E1, AC008764.3, AC008764.5, AC008764.8, MED26, AC008764.4, AC008764.7, AC008764.9, AC008764.10, AC008764.2, AC024075.3, SMIM7, AC024075.2, AC024075.1, TMEM38A, AC008737.2, NWD1, AC008737.3, SIN3B, AC008737.1, F2RL3, CPAMD8, RN7SL835P, RN7SL823P, AC020908.2, HAUS8, AC020908.1, MYO9B, AC020908.3, AC020913.1, AC020913.3, AC020913.2, USE1, OCEL1, NR2F6, AC010646.1, USHBP1, BABAM1, AC010463.1, ANKLE1, ABHD8, MRPL34, AC010463.3, DDA1, ANO8, GTPBP3, PLVAP, AC010463.2, CCDC194, BST2, BISPR.
- chr19:17,414,257–17,422,324, 1 gene, copy number 5: AC010319.4.
- chr19:30,219,666–58,605,223, 1,624 genes, copy number 5 (broad region; genes not listed).
- chr22:37,823,382–39,385,575, 85 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr22:39,743,044–39,893,864, 1 gene, copy number 5 (within-gene range 2–5): ENTHD1.
- chr22:39,874,255–46,762,563, 216 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,369. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
